Somatic mutation profile of tumor specimen TCGA-QG-A5YX-01A (aliquot TCGA-QG-A5YX-01A-11D-A28G-10) from TCGA case TCGA-QG-A5YX, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.9 years (22,617 days).
Specimen TCGA-QG-A5YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05d24351-6e0f-41b8-8e83-fd2248bab12c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QG-A5YX-10A (Blood Derived Normal), aliquot TCGA-QG-A5YX-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebc243a1-cc16-469a-9cb4-c16f742ee877

The open-access MAF lists 110 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 24, 3'UTR 7, Frame Shift Del 7, Intron 5, Frame Shift Ins 4, Nonsense Mutation 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 74/165 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 60/133 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SDHA | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs200397144, CM117613, COSV53768691; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 59/89 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs587782289, CM1411658, COSV52672888, COSV52675514, COSV52783032; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV57653855, COSV57662082; called by muse, mutect2, varscan2
- ANKRD34A | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60161814; called by muse, mutect2, varscan2
- ANKRD49 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.783); catalogued as rs369504802; called by muse, mutect2, varscan2
- AP4M1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs754386660; called by muse, mutect2
- ATP10A | c.3250C>T p.R1084* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | catalogued as rs1473756733; called by muse, mutect2, varscan2
- BCR | c.1974+1G>C p.X658_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100006723; called by muse, mutect2, varscan2
- CCDC3 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.241); catalogued as COSV66559153, COSV66560289; called by muse, mutect2, varscan2
- CD177 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs757644378, COSV100946009; called by muse, varscan2
- COG1 | c.2475C>G p.D825E | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533834836, COSV55428213; called by muse, mutect2, varscan2
- DNAI1 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs779968040; called by muse, mutect2, varscan2
- EDIL3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56908131; called by muse, mutect2, varscan2
- EHBP1L1 | c.2760G>T p.E920D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as rs770611619; called by muse, mutect2, varscan2
- EML5 | c.4837C>T p.R1613* (on ENST00000380664; = p.R1621* on NM_183387.3) | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV61351864; called by muse, mutect2, varscan2
- FBXW7 | c.1979del p.L660Qfs*47 (on ENST00000281708 / NM_001349798.2; = p.L580Qfs*47 on NM_018315.5) | Frame Shift Del (DEL) | VAF 41/114 reads (36%) | catalogued as COSV55915890; called by mutect2, pindel, varscan2
- FLG2 | c.6503C>A p.T2168K | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as COSV101165539, COSV66170716; called by muse, mutect2, varscan2
- FNDC1 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs763950052; called by muse, mutect2, varscan2
- GABRB3 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100161688; called by muse, mutect2, varscan2
- GFOD1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as rs1562234788; called by muse, mutect2, varscan2
- GOLGA7 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as COSV63299638; called by muse, mutect2, varscan2
- KCNA5 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282744226, COSV52906994, COSV99364123; called by muse, mutect2, varscan2
- KIAA1671 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs778689439; called by muse, mutect2, varscan2
- MARCHF3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs759245490; called by muse, mutect2, varscan2
- MEIS1 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs758233459; called by muse, mutect2, varscan2
- MYPN | c.3580C>T p.R1194C | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762310456, COSV62731478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781766556, COSV55724746; called by muse, mutect2, varscan2
- OBSCN | c.5666C>T p.A1889V | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs752268935, COSV99486394; called by muse, mutect2, varscan2
- PCDH19 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55260143; called by muse, mutect2, varscan2
- PCDHA12 | c.2286G>T p.E762D | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as rs782480713, COSV56536553; called by muse, mutect2, varscan2
- PDILT | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs747898472, COSV56699985, COSV56701372; called by muse, mutect2, varscan2
- PINX1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs779941568, COSV59111109; called by muse, mutect2, varscan2
- RDH8 | c.979C>T p.R327W (on ENST00000651512; = p.R307W on NM_015725.4) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs750761940, COSV50677698; called by muse, mutect2, varscan2
- RIPK1 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV99454395; called by muse, mutect2, varscan2
- ROBO4 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.543); catalogued as rs372037630, COSV60628590; called by muse, mutect2, varscan2
- RPAP1 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs143671800; called by muse, mutect2, varscan2
- STARD10 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201289203; called by muse, mutect2, varscan2
- STOX2 | c.1664G>A p.C555Y | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV57855363; called by muse, mutect2, varscan2
- SYT1 | c.927C>T p.S309= | Splice Region (SNP) | VAF 55/116 reads (47%) | catalogued as rs375690617; called by muse, mutect2, varscan2
- TNK2 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57374481; called by muse, mutect2, varscan2
- TOGARAM2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as rs545596352, COSV65422691; called by muse, mutect2, varscan2
- TPCN1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs1489813527, COSV59236317; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 39/78 reads (50%) | catalogued as rs760213136; called by mutect2, varscan2
- UNC80 | c.2011C>A p.R671S | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV55883459; called by muse, mutect2
- WASL | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1259802862, COSV56133561, COSV99771531; called by muse, mutect2, varscan2
- XKR6 | c.1697G>T p.R566I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58655817; called by muse, mutect2, varscan2
- YME1L1 | c.933C>A p.N311K (on ENST00000326799 / NM_139312.3; = p.N254K on NM_014263.4) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV58761175; called by muse, mutect2, varscan2
- ZNF646 | c.5270G>A p.R1757Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs756610068, COSV54922827, COSV54924024; called by muse, mutect2, varscan2
- ADAMTS2 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- AXIN2 | c.905dup p.S303Ifs*3 | Frame Shift Ins (INS) | VAF 116/200 reads (58%) | called by mutect2, varscan2
- AXIN2 | c.374_390del p.T125Sfs*10 | Frame Shift Del (DEL) | VAF 52/193 reads (27%) | called by mutect2, pindel, varscan2
- COL6A6 | c.4807G>A p.G1603S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPS6 | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- EVPL | c.4847A>G p.E1616G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GPR179 | c.3869dup p.R1291Efs*59 (on ENST00000621958; = p.R1290Efs*59 on NM_001004334.4) | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- GSDMC | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- HLA-G | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNF1B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ISL2 | c.168del p.E57Sfs*14 | Frame Shift Del (DEL) | VAF 50/150 reads (33%) | called by mutect2, pindel, varscan2
- LRRC19 | c.1043T>C p.F348S | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MDN1 | c.3298G>C p.A1100P | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ODAM | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PHTF1 | c.760dup p.S254Ffs*8 | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.5645del p.K1882Rfs*40 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2251_2263del p.H751Kfs*162 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- SLC9A7 | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMAD4 | c.1619_1625del p.L540Pfs*10 | Frame Shift Del (DEL) | VAF 17/26 reads (65%) | called by mutect2, pindel, varscan2
- STAG1 | c.2815G>T p.G939C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by mutect2, varscan2
- TMEM39A | c.239dup p.I81Hfs*16 | Frame Shift Ins (INS) | VAF 40/114 reads (35%) | called by mutect2, varscan2
- TNR | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VEGFC | c.208A>C p.M70L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.924); called by muse, varscan2
- ZNF547 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AHNAK2 | c.2850G>A p.A950= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as rs779221842, COSV60907959; called by muse, mutect2, varscan2
- CASKIN1 | c.1893C>T p.I631= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs759641819, COSV100399707; called by muse, mutect2, varscan2
- CHD5 | c.675G>A p.P225= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs201998865, COSV52408560; called by muse, mutect2, varscan2
- DNAH1 | c.2931C>T p.N977= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs377200347; called by muse, mutect2, varscan2
- EXD3 | c.258C>T p.C86= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs376173264; called by muse, mutect2, varscan2
- FAT2 | c.9753C>T p.T3251= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as rs769890468; called by muse, mutect2, varscan2
- FBLN1 | c.1254G>A p.T418= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1194623370, COSV53052649; called by muse, mutect2, varscan2
- FBN3 | c.6627C>T p.D2209= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs145531691, COSV54454813; called by muse, mutect2, varscan2
- HHIPL2 | c.1872G>A p.P624= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs749643311, COSV58563398; called by muse, mutect2, varscan2
- IDH3B | c.6G>A p.A2= | Silent (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- KRT27 | c.558C>T p.S186= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV56971364; called by muse, mutect2
- LAMA5 | c.2790C>T p.L930= | Silent (SNP) | VAF 68/220 reads (31%) | catalogued as rs765293167, COSV53370900; called by muse, mutect2, varscan2
- MMP16 | c.942G>A p.P314= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs750281570, COSV54164710; called by mutect2, varscan2
- MYRIP | c.1185C>T p.S395= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs755885859; called by muse, mutect2, varscan2
- OMD | c.747C>T p.P249= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs145619571; called by muse, mutect2, varscan2
- PCDH8 | c.1287C>T p.C429= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV58812675; called by muse, mutect2, varscan2
- PCDHB5 | c.1527C>T p.N509= | Silent (SNP) | VAF 95/202 reads (47%) | catalogued as rs377744960; called by muse, mutect2, varscan2
- PCDHGB1 | c.1899G>A p.A633= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54010626; called by muse, mutect2, varscan2
- PGC | c.264C>A p.V88= | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1404G>A p.P468= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs754382230, COSV100177280, COSV59998477; called by muse, mutect2, varscan2
- RTL1 | c.1611G>A p.P537= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1291867786, COSV66016602; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC22A12 | c.789G>T p.L263= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- TCERG1L | c.1635C>T p.Y545= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs369936170; called by muse, mutect2, varscan2
- TSC2 | c.3543G>A p.T1181= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs139313964; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMDHD2 | c.970+25C>G | Intron (SNP) | VAF 71/183 reads (39%) | catalogued as rs1284018547; called by muse, mutect2, varscan2
- ARPP21 | c.898-10del | Intron (DEL) | VAF 20/51 reads (39%) | catalogued as rs751740483; called by mutect2, varscan2
- CMTM5 | c.*41G>A | 3'UTR (SNP) | VAF 10/18 reads (56%) | catalogued as rs879488667, COSV100198106; called by muse, mutect2, varscan2
- DIO3 | c.*247G>A | 3'UTR (SNP) | VAF 46/138 reads (33%) | catalogued as COSV100832160; called by muse, mutect2, varscan2
- FGFR1 | c.937-1208G>A | Intron (SNP) | VAF 28/106 reads (26%) | catalogued as rs779349993, COSV58329322; called by muse, mutect2, varscan2
- FUT9 | c.*2230del | 3'UTR (DEL) | VAF 15/39 reads (38%) | catalogued as rs1011848246; called by mutect2, varscan2
- GAD1 | c.639-1427C>A | Intron (SNP) | VAF 99/192 reads (52%) | catalogued as COSV100713873; called by muse, mutect2, varscan2
- PCDHB15 | c.*26G>A | 3'UTR (SNP) | VAF 15/52 reads (29%) | catalogued as rs782810320, COSV50970790; called by muse, mutect2, varscan2
- PCDHB2 | c.*32G>A | 3'UTR (SNP) | VAF 57/140 reads (41%) | catalogued as rs547378848, COSV99164140; called by muse, mutect2, varscan2
- SERTM1 | c.*2082dup | 3'UTR (INS) | VAF 14/55 reads (25%) | catalogued as rs397691773, COSV59375581; called by mutect2, pindel, varscan2
- SRSF10 | c.*3469G>A | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- TMEM9 | c.66+60C>G | Intron (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
